Somatic mutation profile of tumor specimen TCGA-L9-A5IP-01A (aliquot TCGA-L9-A5IP-01A-21D-A397-08) from TCGA case TCGA-L9-A5IP, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IV; Age at diagnosis: 40.2 years (14,681 days).
Specimen TCGA-L9-A5IP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fc9e5a45-f6cb-4615-a29c-10ad705a2382.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L9-A5IP-10A (Blood Derived Normal), aliquot TCGA-L9-A5IP-10A-01D-A39A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d9ed62be-f357-4a24-b887-b1f4ba5228b4

The open-access MAF lists 312 somatic variants for this specimen: 236 protein-altering or splice-affecting, 71 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 205, Silent 71, Splice Site 9, Frame Shift Del 8, Nonsense Mutation 8, Splice Region 4, 5'Flank 2, Intron 2, Frame Shift Ins 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.3975-1G>T p.X1325_splice | Splice Site (SNP) | VAF 37/65 reads (57%) | catalogued as rs1060500370, CS153440, COSV100647043, COSV62200559; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 23/37 reads (62%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs786201059, CM076567, CM1212545, COSV52664318, COSV52687201, COSV52688214; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.11943G>T p.K3981N | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748058574, COSV101446956; called by muse, mutect2, varscan2
- ABCD2 | c.793T>A p.Y265N | Missense Mutation (SNP) | VAF 52/87 reads (60%) | SIFT tolerated (0.29); PolyPhen benign (0.356); catalogued as COSV100429444; called by muse, mutect2, varscan2
- ACAP2 | c.2135G>T p.S712I | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV100462077; called by muse, mutect2, varscan2
- ACD | c.659G>T p.R220L (on ENST00000620338; = p.R131L on NM_022914.3) | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV99537689; called by muse, mutect2, varscan2
- ACSM2B | c.1449G>T p.M483I | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100312656; called by muse, mutect2, varscan2
- ACSM5 | c.1661C>A p.A554D | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.217); catalogued as COSV100088906; called by muse, mutect2, varscan2
- ACVR1B | c.1137-2A>C p.X379_splice | Splice Site (SNP) | VAF 93/156 reads (60%) | catalogued as COSV99231489; called by muse, mutect2, varscan2
- ACVR1B | c.1137-1G>T p.X379_splice | Splice Site (SNP) | VAF 94/155 reads (61%) | catalogued as COSV57781527; called by muse, mutect2, varscan2
- ADAMTS12 | c.3187G>T p.G1063C | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.237); catalogued as COSV100710922; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1343G>A p.C448Y | Missense Mutation (SNP) | VAF 48/86 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1378609082, COSV99442690; called by muse, mutect2, varscan2
- ADGRF2 | c.1069G>T p.E357* (on ENST00000296862 / NM_001368115.2; = p.E289* on NM_153839.7) | Nonsense Mutation (SNP) | VAF 55/105 reads (52%) | catalogued as rs1322902826, COSV99731196; called by muse, mutect2, varscan2
- AKAP9 | c.10858A>T p.T3620S (on ENST00000359028; = p.T3596S on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100662288, COSV100662385; called by muse, mutect2, varscan2
- ANK2 | c.3295A>T p.S1099C | Missense Mutation (SNP) | VAF 42/72 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100001608; called by muse, mutect2, varscan2
- ANKRD13C | c.1112C>T p.S371L | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV99256833; called by muse, mutect2, varscan2
- AOC1 | c.448C>A p.L150I | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.721); catalogued as COSV62869042; called by muse, mutect2, varscan2
- APCS | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as COSV54818615; called by muse, mutect2, varscan2
- APOH | c.872T>C p.L291P | Missense Mutation (SNP) | VAF 48/91 reads (53%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.654); catalogued as COSV99079595, COSV99235762; called by muse, mutect2, varscan2
- ARHGAP4 | c.1229C>T p.S410F | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100604037; called by muse, mutect2, varscan2
- ARHGAP4 | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100604040; called by muse, mutect2, varscan2
- ARL14EP | c.751G>C p.G251R | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99955939; called by muse, mutect2, varscan2
- ATG4D | c.490A>T p.R164* | Nonsense Mutation (SNP) | VAF 31/61 reads (51%) | catalogued as COSV100521020; called by muse, mutect2, varscan2
- BBS2 | c.1297A>T p.S433C | Missense Mutation (SNP) | VAF 45/94 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.669); catalogued as COSV99802403; called by muse, mutect2, varscan2
- BMPER | c.1375G>A p.D459N | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as COSV51821897; called by muse, mutect2, varscan2
- BRINP2 | c.56G>T p.W19L | Missense Mutation (SNP) | VAF 37/60 reads (62%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.991); catalogued as rs1474176186, COSV100838079; called by muse, mutect2, varscan2
- C2orf16 | c.4888C>A p.L1630I | Missense Mutation (SNP) | VAF 69/169 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV100820800; called by muse, mutect2, varscan2
- C3orf20 | c.660C>A p.N220K | Missense Mutation (SNP) | VAF 37/64 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as COSV99513934; called by muse, mutect2, varscan2
- C5 | c.2884A>T p.R962W | Missense Mutation (SNP) | VAF 68/145 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as COSV99797851; called by muse, mutect2, varscan2
- CALN1 | c.204G>T p.L68F (on ENST00000329008 / NM_001017440.3; = p.L110F on NM_031468.4) | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV61146567; called by muse, mutect2, varscan2
- CATSPERD | c.1224G>T p.Q408H | Missense Mutation (SNP) | VAF 79/144 reads (55%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.693); catalogued as COSV100486788; called by muse, mutect2, varscan2
- CCDC151 | c.353T>A p.L118Q | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.074); catalogued as COSV99371602; called by muse, mutect2, varscan2
- CCDC178 | c.108G>C p.R36S | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT tolerated (0.74); PolyPhen benign (0.037); catalogued as COSV100284868; called by muse, mutect2, varscan2
- CCDC74B | c.624G>T p.E208D | Missense Mutation (SNP) | VAF 36/181 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as COSV99064177; called by muse, mutect2, varscan2
- CD207 | c.772G>A p.A258T | Missense Mutation (SNP) | VAF 63/127 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.267); catalogued as COSV101338560; called by muse, mutect2, varscan2
- CDH12 | c.87G>T p.Q29H | Missense Mutation (SNP) | VAF 61/206 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.135); catalogued as COSV66403980; called by muse, mutect2, varscan2
- CDH6 | c.2307C>A p.D769E | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT tolerated (0.48); PolyPhen benign (0.011); catalogued as COSV99419143; called by muse, mutect2, varscan2
- CENPF | c.929G>T p.G310V | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as COSV100871689; called by muse, mutect2, varscan2
- CERCAM | c.303G>T p.E101D | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.058); catalogued as COSV100864004; called by muse, mutect2, varscan2
- CNTN1 | c.2806A>G p.T936A | Missense Mutation (SNP) | VAF 31/52 reads (60%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100751377; called by muse, mutect2, varscan2
- CNTNAP5 | c.2144C>A p.P715H | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV101443535; called by muse, mutect2, varscan2
- COG3 | c.823A>G p.T275A | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.754); catalogued as rs1338025864, COSV100596511; called by muse, mutect2, varscan2
- COL4A2 | c.797G>T p.G266V | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV100847345; called by muse, mutect2, varscan2
- CPAMD8 | c.2878G>T p.A960S (on ENST00000651564; = p.A913S on NM_015692.5) | Missense Mutation (SNP) | VAF 37/67 reads (55%) | SIFT tolerated (0.52); PolyPhen benign (0.107); catalogued as COSV101488516, COSV101488587; called by muse, mutect2, varscan2
- CSF2RB | c.2148C>A p.D716E | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.896); catalogued as rs753718810, COSV99453872; called by muse, mutect2, varscan2
- CSMD3 | c.1227C>A p.N409K | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.023); catalogued as COSV52121272; called by muse, varscan2
- CYP4F2 | c.871G>T p.A291S | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.183); catalogued as COSV99171079; called by muse, mutect2, varscan2
- CYSLTR2 | c.162G>T p.L54F | Missense Mutation (SNP) | VAF 37/67 reads (55%) | SIFT tolerated (0.26); PolyPhen benign (0.092); catalogued as COSV99935232; called by muse, mutect2, varscan2
- DEFB123 | c.137G>C p.C46S | Missense Mutation (SNP) | VAF 38/68 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1383006365, COSV66232964; called by muse, mutect2, varscan2
- DLX5 | c.111G>T p.L37F | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99756480; called by muse, mutect2, varscan2
- DMKN | c.1022G>C p.G341A | Missense Mutation (SNP) | VAF 59/97 reads (61%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.747); catalogued as COSV100303578; called by muse, mutect2, varscan2
- DNAH3 | c.7842T>G p.D2614E | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as COSV99767398; called by muse, mutect2
- DNAH8 | c.2467G>A p.D823N | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.5); PolyPhen benign (0.01); catalogued as COSV100545230; called by muse, mutect2, varscan2
- DNAJC4 | c.184C>T p.H62Y | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1326001643, COSV99655849; called by muse, mutect2, varscan2
- DSG1 | c.1025T>A p.M342K | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as COSV99936008; called by muse, mutect2, varscan2
- DTNA | c.1033A>T p.M345L | Missense Mutation (SNP) | VAF 43/83 reads (52%) | SIFT tolerated (0.77); PolyPhen benign (0.028); catalogued as COSV99312746; called by muse, mutect2, varscan2
- DUSP22 | c.25C>A p.L9M | Missense Mutation (SNP) | VAF 63/274 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.708); catalogued as COSV100739756; called by muse, mutect2, varscan2
- DYNC2H1 | c.12671G>T p.G4224V | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100518558; called by muse, mutect2
- F13A1 | c.1909-2A>T p.X637_splice | Splice Site (SNP) | VAF 23/51 reads (45%) | catalogued as COSV99342997; called by muse, mutect2, varscan2
- F5 | c.3370G>A p.E1124K | Missense Mutation (SNP) | VAF 92/158 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as COSV100889100; called by muse, mutect2, varscan2
- FAM135B | c.656C>A p.P219Q | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.52); PolyPhen probably damaging (1); catalogued as rs200971969, COSV52709088, COSV99423894; called by muse, mutect2, varscan2
- FAM47B | c.1547A>T p.D516V | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV100264327; called by muse, mutect2, varscan2
- FAM83B | c.1688C>A p.S563Y | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.956); catalogued as COSV100174467, COSV60927369; called by muse, mutect2, varscan2
- FBN3 | c.7916G>T p.G2639V | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1252137957, COSV99560906; called by muse, mutect2, varscan2
- FER | c.1237-1G>T p.X413_splice | Splice Site (SNP) | VAF 38/86 reads (44%) | catalogued as rs1169843631, COSV55285117; called by muse, mutect2, varscan2
- FLG | c.1754G>A p.G585E | Missense Mutation (SNP) | VAF 82/489 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372282962; called by muse, mutect2, varscan2
- FLRT3 | c.1785G>T p.Q595H | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV99432551; called by muse, mutect2, varscan2
- GIMAP6 | c.803G>T p.W268L | Missense Mutation (SNP) | VAF 46/75 reads (61%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100188227; called by muse, mutect2, varscan2
- GK | c.336G>T p.V112= | Splice Region (SNP) | VAF 22/47 reads (47%) | catalogued as COSV100970650; called by muse, mutect2, varscan2
- GOLGA3 | c.1030A>G p.M344V | Missense Mutation (SNP) | VAF 37/64 reads (58%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs756629270, COSV99204659; called by muse, mutect2, varscan2
- GON4L | c.6029C>A p.S2010Y | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.365); catalogued as COSV99674258; called by muse, mutect2
- GPR3 | c.745C>G p.L249V | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.996); catalogued as COSV100927519; called by muse, mutect2, varscan2
- GRM8 | c.1683A>T p.R561S | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.105); catalogued as COSV100282908; called by muse, mutect2, varscan2
- HERC1 | c.13205G>A p.R4402Q | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.342); catalogued as rs369029117, COSV101496560; called by muse, mutect2, varscan2
- HGF | c.2010G>A p.E670= | Splice Region (SNP) | VAF 34/113 reads (30%) | catalogued as COSV99736937; called by muse, mutect2, varscan2
- HMCN1 | c.2317G>C p.V773L | Missense Mutation (SNP) | VAF 27/201 reads (13%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.979); catalogued as COSV99629178; called by muse, mutect2, varscan2
- HOXA9 | c.544A>T p.N182Y | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as COSV100604406; called by muse, mutect2, varscan2
- IBTK | c.1879A>G p.M627V | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as COSV100090716; called by muse, mutect2, varscan2
- IFI44L | c.509G>T p.R170M | Missense Mutation (SNP) | VAF 44/80 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV60729172; called by muse, mutect2, varscan2
- IL17RD | c.2191G>T p.D731Y | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.466); catalogued as COSV99577148; called by muse, mutect2, varscan2
- IL18R1 | c.488T>G p.L163R | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0.286); catalogued as rs1213082799, COSV99295098; called by muse, mutect2, varscan2
- IL7R | c.973C>A p.Q325K | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.233); catalogued as COSV100286273, COSV57409288; called by muse, mutect2, varscan2
- INTS6L | c.906A>G p.L302= | Splice Region (SNP) | VAF 77/160 reads (48%) | catalogued as COSV100878111; called by muse, mutect2, varscan2
- INTS9 | c.273A>G p.I91M | Missense Mutation (SNP) | VAF 32/50 reads (64%) | SIFT tolerated (0.14); PolyPhen benign (0.181); catalogued as COSV68433130; called by muse, mutect2, varscan2
- ITGA4 | c.94C>A p.R32S | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.79); PolyPhen benign (0.019); catalogued as rs1210805587, COSV99276302; called by muse, mutect2, varscan2
- ITK | c.745G>T p.A249S | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.841); catalogued as rs1280985491, COSV101346685, COSV68435395; called by muse, mutect2, varscan2
- KCNH5 | c.2331C>A p.N777K | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0.007); catalogued as COSV100526562; called by muse, mutect2, varscan2
- KCNK18 | c.950G>T p.C317F | Missense Mutation (SNP) | VAF 95/180 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as rs771838477, COSV100571950, COSV100572041; called by muse, mutect2, varscan2
- KCNK9 | c.1112G>A p.R371Q | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs1471072625, COSV57278542, COSV57284128; called by muse, mutect2, varscan2
- KCNN2 | c.559G>T p.V187L (on ENST00000264773; = p.V399L on NM_021614.4) | Missense Mutation (SNP) | VAF 36/53 reads (68%) | SIFT tolerated (0.77); PolyPhen benign (0.007); catalogued as COSV99299748; called by muse, mutect2, varscan2
- KCTD3 | c.2261G>T p.R754M | Missense Mutation (SNP) | VAF 78/129 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.466); catalogued as COSV99379235; called by muse, mutect2, varscan2
- KMT2A | c.9524C>T p.P3175L | Missense Mutation (SNP) | VAF 57/102 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.895); catalogued as COSV63289797; called by muse, mutect2, varscan2
- KPRP | c.624C>A p.F208L | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.003); catalogued as rs764225483, COSV100908736, COSV64221008; called by muse, mutect2, varscan2
- KRBA1 | c.2551G>T p.A851S | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.07); PolyPhen benign (0.202); catalogued as rs1391139766, COSV99752664; called by muse, mutect2, varscan2
- KRTAP10-6 | c.589C>A p.Q197K | Missense Mutation (SNP) | VAF 52/109 reads (48%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as COSV100553480; called by muse, mutect2, varscan2
- KYAT3 | c.1355A>T p.Q452L | Missense Mutation (SNP) | VAF 39/56 reads (70%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV99556190; called by muse, mutect2, varscan2
- LAMC3 | c.802G>A p.G268S | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100735978; called by muse, mutect2, varscan2
- LAP3 | c.630G>T p.M210I | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.033); catalogued as COSV99884299; called by muse, mutect2
- LINGO2 | c.1189C>A p.H397N | Missense Mutation (SNP) | VAF 41/66 reads (62%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV100430551; called by muse, mutect2, varscan2
- LRRC42 | c.88G>T p.A30S | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.66); PolyPhen benign (0.009); catalogued as COSV59961612; called by muse, mutect2, varscan2
- MAGI2 | c.3694G>T p.V1232F | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100834490; called by muse, mutect2, varscan2
- MAL | c.70G>T p.D24Y | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1418051696, COSV100015761; called by muse, mutect2, varscan2
- MAST3 | c.3848G>C p.G1283A | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV99445283; called by muse, mutect2, varscan2
- MBP | c.611G>A p.G204D (on ENST00000355994 / NM_001025101.2; = p.G97D on NM_002385.3) | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs763871565, COSV100592648; called by muse, mutect2, varscan2
- MC2R | c.169G>T p.A57S | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100562998; called by muse, mutect2, varscan2
- MEGF10 | c.1727G>T p.R576L | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT tolerated (0.75); PolyPhen benign (0.297); catalogued as rs201832505; called by muse, mutect2, varscan2
- MICAL3 | c.1610G>T p.G537V | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99261514; called by muse, mutect2, varscan2
- MIGA2 | c.340A>T p.S114C | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.701); catalogued as rs1290894595, COSV99477603; called by muse, mutect2, varscan2
- MMP25 | c.453G>A p.M151I | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV60678581; called by muse, mutect2, varscan2
- MON1A | c.422C>T p.A141V | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.86); catalogued as rs757855583, COSV99616702; called by muse, mutect2, varscan2
- MPHOSPH10 | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 107/238 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1185454371, COSV99732680; called by muse, mutect2, varscan2
- MRPS27 | c.679G>T p.G227C | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99782216; called by muse, mutect2, varscan2
- MRPS9 | c.273G>A p.M91I | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); catalogued as COSV99306069; called by muse, mutect2, varscan2
- MUC2 | c.2035C>A p.R679S | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as rs775778261; called by muse, mutect2, varscan2
- MYO9A | c.6713+1G>T p.X2238_splice | Splice Site (SNP) | VAF 12/62 reads (19%) | catalogued as COSV100613491; called by muse, mutect2, varscan2
- MYOF | c.5834C>T p.S1945F | Missense Mutation (SNP) | VAF 171/498 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV63704003; called by muse, mutect2, varscan2
- NAE1 | c.733G>T p.D245Y | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as COSV99323123; called by muse, mutect2, varscan2
- NCAM2 | c.1384-1G>T p.X462_splice | Splice Site (SNP) | VAF 74/152 reads (49%) | catalogued as COSV99522987; called by muse, mutect2, varscan2
- NCOA7 | c.706G>C p.V236L | Missense Mutation (SNP) | VAF 85/179 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99997090; called by muse, mutect2, varscan2
- NEB | c.3646G>C p.V1216L | Missense Mutation (SNP) | VAF 97/307 reads (32%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.981); catalogued as COSV99422632; called by muse, mutect2, varscan2
- NEDD4 | c.1148G>A p.R383Q | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs746298752, COSV100163716; called by muse, mutect2, varscan2
- NEFH | c.1730A>T p.E577V | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV100151554; called by muse, mutect2, varscan2
- NIM1K | c.62G>T p.R21L | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.045); catalogued as COSV100390153; called by muse, mutect2, varscan2
- NLRP12 | c.1262G>T p.G421V | Missense Mutation (SNP) | VAF 110/169 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100145269; called by muse, mutect2, varscan2
- NLRP3 | c.2212A>T p.S738C | Missense Mutation (SNP) | VAF 94/151 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV100276025; called by muse, mutect2, varscan2
- NMUR2 | c.494G>T p.R165M | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV99676491, COSV99676881; called by muse, mutect2, varscan2
- NOD1 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs139576372, COSV56114694; called by muse, mutect2, varscan2
- NOS1 | c.2171C>A p.T724N | Missense Mutation (SNP) | VAF 92/150 reads (61%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV100500578; called by muse, mutect2, varscan2
- NRCAM | c.2411C>G p.S804C (on ENST00000379028 / NM_001371124.1; = p.S788C on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.766); catalogued as rs201534122, COSV100694682, COSV61039374; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NRK | c.2527G>T p.E843* | Nonsense Mutation (SNP) | VAF 7/11 reads (64%) | catalogued as rs1199085148, COSV99687743; called by muse, mutect2, varscan2
- NUTM1 | c.2587C>A p.Q863K | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as COSV100149003; called by muse, mutect2, varscan2
- NUTM2G | c.522C>A p.N174K | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT tolerated (0.83); PolyPhen benign (0.058); catalogued as rs547050979, COSV100672841, COSV63616837; called by mutect2, varscan2
- NVL | c.1934C>T p.S645F | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99894258; called by muse, mutect2, varscan2
- OBSCN | c.17008C>G p.P5670A | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as COSV99477765; called by muse, mutect2, varscan2
- OLFML2A | c.499G>A p.V167M | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.61); PolyPhen benign (0.026); catalogued as COSV99992592; called by muse, mutect2, varscan2
- OR2T10 | c.650C>G p.S217C | Missense Mutation (SNP) | VAF 60/77 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100393704; called by muse, mutect2, varscan2
- OR3A1 | c.892C>A p.P298T | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs760005941, COSV100041666; called by muse, mutect2, varscan2
- OR52A1 | c.709A>G p.R237G | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as rs756239666, COSV100200489; called by muse, mutect2, varscan2
- OR7G3 | c.117G>T p.M39I | Missense Mutation (SNP) | VAF 31/53 reads (58%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100555673; called by muse, mutect2
- OTOP1 | c.1688T>A p.F563Y | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99587668; called by muse, mutect2, varscan2
- OVCH1 | c.1794C>A p.Y598* | Nonsense Mutation (SNP) | VAF 24/37 reads (65%) | catalogued as COSV100548165, COSV100548586; called by muse, mutect2, varscan2
- P2RY10 | c.910C>T p.L304F | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as rs1001194534, COSV50681883, COSV99409100; called by muse, mutect2, varscan2
- PCDHB2 | c.2342C>A p.A781E | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); catalogued as rs1554271732, COSV99165156; called by muse, mutect2, varscan2
- PEG3 | c.3410G>T p.S1137I | Missense Mutation (SNP) | VAF 75/115 reads (65%) | SIFT tolerated (0.08); PolyPhen benign (0.308); catalogued as COSV99688906; called by muse, mutect2, varscan2
- PHKB | c.1881A>G p.R627= | Splice Region (SNP) | VAF 34/84 reads (40%) | catalogued as COSV100067046; called by muse, mutect2, varscan2
- PIK3CG | c.2310G>T p.K770N | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.379); catalogued as COSV100782873; called by muse, mutect2, varscan2
- PKD1L1 | c.7835G>T p.R2612L | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as COSV99219692; called by muse, mutect2, varscan2
- PKD1L1 | c.7143G>T p.Q2381H | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1324183439, COSV99219695; called by muse, mutect2, varscan2
- PKHD1L1 | c.343A>T p.S115C | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV101006133; called by muse, mutect2, varscan2
- POM121L12 | c.549C>A p.S183R | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.72); PolyPhen benign (0.031); catalogued as rs1443762548, COSV101374916; called by muse, mutect2, varscan2
- POSTN | c.283+1G>T p.X95_splice | Splice Site (SNP) | VAF 28/52 reads (54%) | catalogued as COSV101123329; called by muse, mutect2, varscan2
- PRAMEF4 | c.929A>T p.E310V | Missense Mutation (SNP) | VAF 147/349 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99339827; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.842G>T p.G281V (on ENST00000352766; = p.G158V on NM_181334.5) | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100424255; called by muse, mutect2, varscan2
- PSMA1 | c.12C>A p.S4R | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as COSV101335674; called by muse, mutect2, varscan2
- PXDNL | c.3976C>A p.P1326T | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.109); catalogued as rs767204951, COSV62490113; called by muse, mutect2, varscan2
- RAD51AP2 | c.2111G>T p.R704I | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.366); catalogued as COSV101208340; called by muse, mutect2, varscan2
- RARA | c.492G>C p.K164N | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as rs1481572813, COSV99564995; called by muse, mutect2, varscan2
- RBBP6 | c.2611A>T p.R871W | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.903); catalogued as COSV100154592; called by muse, mutect2, varscan2
- RFX1 | c.1314+1G>T p.X438_splice | Splice Site (SNP) | VAF 15/29 reads (52%) | catalogued as rs1458566273, COSV99586074; called by muse, mutect2, varscan2
- RFX6 | c.516G>C p.Q172H | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV100263733; called by muse, mutect2, varscan2
- RINT1 | c.2248G>T p.V750L | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.151); catalogued as COSV99994389; called by muse, mutect2, varscan2
- RNF145 | c.476G>T p.R159L (on ENST00000424310 / NM_001199383.2; = p.R187L on NM_144726.2) | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99193522; called by muse, mutect2, varscan2
- ROR2 | c.614G>C p.R205P | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100995808, COSV100995931; called by muse, mutect2, varscan2
- RP1 | c.1285A>T p.T429S | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99607466; called by muse, mutect2, varscan2
- RPL10L | c.578A>G p.D193G | Missense Mutation (SNP) | VAF 46/75 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV100022562; called by muse, mutect2, varscan2
- RXRG | c.287C>A p.P96H | Missense Mutation (SNP) | VAF 35/53 reads (66%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV100717539; called by muse, mutect2, varscan2
- RYR2 | c.6188C>T p.S2063F | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100770098; called by muse, mutect2, varscan2
- SAGE1 | c.2162A>G p.H721R | Missense Mutation (SNP) | VAF 55/113 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV100187221; called by muse, mutect2, varscan2
- SALL3 | c.265C>T p.P89S | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.66); PolyPhen benign (0.251); catalogued as COSV101609997; called by muse, mutect2, varscan2
- SCLT1 | c.686G>T p.R229M | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1481337872, COSV55408124; called by muse, mutect2, varscan2
- SETD5 | c.174T>A p.Y58* | Nonsense Mutation (SNP) | VAF 49/79 reads (62%) | catalogued as COSV100200604; called by muse, mutect2, varscan2
- SH3RF1 | c.2233G>T p.E745* | Nonsense Mutation (SNP) | VAF 25/37 reads (68%) | catalogued as COSV99499019; called by muse, mutect2, varscan2
- SHC1 | c.410A>T p.H137L (on ENST00000368445 / NM_183001.5; = p.H27L on NM_003029.5) | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.04); catalogued as COSV100460422; called by muse, mutect2
- SLC14A1 | c.316A>T p.M106L | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV100425052; called by muse, mutect2, varscan2
- SLC16A13 | c.25G>A p.D9N | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100340130; called by muse, mutect2, varscan2
- SLC30A8 | c.424del p.G143Vfs*12 | Frame Shift Del (DEL) | VAF 54/222 reads (24%) | catalogued as COSV101438488; called by mutect2, pindel, varscan2
- SLFN11 | c.1825G>T p.A609S | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100390632; called by muse, mutect2, varscan2
- SNAPC4 | c.441G>T p.K147N | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100047198; called by muse, mutect2, varscan2
- SNRNP27 | c.44G>C p.R15P | Missense Mutation (SNP) | VAF 75/180 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as COSV54912016, COSV99732083; called by muse, mutect2, varscan2
- SORCS1 | c.1504C>G p.R502G | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.326); catalogued as COSV53855392, COSV99546300; called by muse, mutect2, varscan2
- SPDL1 | c.987A>T p.E329D | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99517545; called by muse, mutect2, varscan2
- SPEF2 | c.1019G>T p.R340L | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99214207, COSV99214224; called by muse, mutect2, varscan2
- SPHKAP | c.1475C>A p.P492H | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.594); catalogued as COSV100764121; called by muse, mutect2, varscan2
- SPRR2D | c.166C>G p.P56A | Missense Mutation (SNP) | VAF 137/262 reads (52%) | SIFT tolerated, low confidence (0.3); PolyPhen probably damaging (0.994); catalogued as rs777414207, COSV100836041; called by muse, mutect2, varscan2
- SPTA1 | c.6034G>C p.A2012P | Missense Mutation (SNP) | VAF 86/516 reads (17%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.852); catalogued as COSV100934916; called by muse, mutect2, varscan2
- SSUH2 | c.594del p.S199Pfs*113 | Frame Shift Del (DEL) | VAF 18/39 reads (46%) | catalogued as rs1343317760, COSV58031137; called by mutect2, pindel, varscan2
- ST6GAL2 | c.494C>A p.A165D | Missense Mutation (SNP) | VAF 55/164 reads (34%) | PolyPhen benign (0); catalogued as COSV100867864; called by muse, mutect2, varscan2
- SUCLG1 | c.919G>T p.G307* | Nonsense Mutation (SNP) | VAF 22/136 reads (16%) | catalogued as rs1436128533, COSV101205410; called by muse, mutect2, varscan2
- SUSD1 | c.2011A>G p.I671V | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.053); catalogued as COSV100813294; called by muse, mutect2, varscan2
- SV2A | c.2001T>A p.N667K | Missense Mutation (SNP) | VAF 28/177 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100975157; called by muse, mutect2, varscan2
- SYNE1 | c.5529G>C p.Q1843H (on ENST00000367255 / NM_182961.4; = p.Q1850H on NM_033071.3) | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.076); catalogued as COSV99563919; called by muse, mutect2, varscan2
- TENM1 | c.4490C>A p.P1497H | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100950019; called by muse, mutect2, varscan2
- TFAP2B | c.314C>G p.P105R | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.159); catalogued as COSV99540185; called by muse, mutect2, varscan2
- TFAP2D | c.674C>T p.S225F | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV50412568; called by muse, mutect2, varscan2
- THBS2 | c.2292G>T p.Q764H | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100827886; called by muse, mutect2, varscan2
- THSD1 | c.2528G>T p.S843I | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1296506894, COSV99318889; called by muse, mutect2, varscan2
- THSD7A | c.892G>C p.E298Q | Missense Mutation (SNP) | VAF 66/146 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.634); catalogued as COSV101448697, COSV70271244, COSV70273354; called by muse, mutect2, varscan2
- TMC5 | c.80A>T p.Q27L | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); catalogued as COSV101196732; called by muse, mutect2, varscan2
- TMOD1 | c.512A>T p.K171M | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as COSV99403862; called by muse, mutect2
- TMTC4 | c.1685G>T p.S562I (on ENST00000376234 / NM_001350577.2; = p.S581I on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV100168683; called by muse, mutect2, varscan2
- TNR | c.1576C>A p.P526T | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV54881708, COSV99689542; called by muse, mutect2, varscan2
- TOX3 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as rs752653368, COSV99567545; called by muse, mutect2, varscan2
- TRAT1 | c.181C>A p.P61T | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1445462382, COSV99849264; called by muse, mutect2, varscan2
- TRPC4 | c.1996C>T p.L666F | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV100156829; called by muse, mutect2, varscan2
- TRPV4 | c.1802C>A p.T601N | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99924693; called by muse, mutect2, varscan2
- TSC2 | c.3087G>A p.M1029I | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); catalogued as COSV54756255, COSV99554076; called by muse, mutect2, varscan2
- TSHZ3 | c.2716C>A p.L906I | Missense Mutation (SNP) | VAF 25/35 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV53668140; called by muse, mutect2, varscan2
- TTC21B | c.3165G>T p.W1055C | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99692297; called by muse, mutect2, varscan2
- UAP1L1 | c.1137A>G p.I379M | Missense Mutation (SNP) | VAF 70/161 reads (43%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.985); catalogued as COSV100814442; called by muse, mutect2, varscan2
- UBOX5 | c.1529G>T p.R510L | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99417888; called by muse, mutect2, varscan2
- USH2A | c.14612C>G p.P4871R | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV100234508; called by muse, mutect2, varscan2
- USH2A | c.14611C>A p.P4871T | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as COSV100234511; called by muse, mutect2, varscan2
- VAX1 | c.26A>T p.D9V | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.5); catalogued as COSV99524129; called by muse, mutect2, varscan2
- VCAN | c.2129G>T p.S710I | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as COSV99425728; called by muse, mutect2, varscan2
- WDHD1 | c.1204G>T p.D402Y | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as rs1566730699, COSV100777580; called by muse, mutect2, varscan2
- WDR17 | c.2542G>A p.A848T | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99707573; called by muse, mutect2, varscan2
- XIRP1 | c.3168G>T p.Q1056H | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1182242089, COSV100453637; called by muse, mutect2, varscan2
- ZFHX4 | c.5280del p.T1761Hfs*7 | Frame Shift Del (DEL) | VAF 11/39 reads (28%) | catalogued as COSV51497949; called by mutect2, pindel, varscan2
- ZFPM2 | c.2596G>T p.V866L | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs371740091, COSV101023217; called by muse, mutect2, varscan2
- ZG16B | c.289T>A p.W97R | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101206756; called by muse, mutect2, varscan2
- ZNF320 | c.1418A>T p.Q473L | Missense Mutation (SNP) | VAF 50/73 reads (68%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.647); catalogued as COSV101206862; called by muse, mutect2, varscan2
- ZNF462 | c.6742G>T p.E2248* | Nonsense Mutation (SNP) | VAF 55/262 reads (21%) | catalogued as COSV99471963; called by muse, mutect2, varscan2
- ZNF560 | c.579T>A p.N193K | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.93); PolyPhen benign (0.116); catalogued as COSV100038610, COSV100039137, COSV56872328; called by muse, mutect2, varscan2
- ZNF639 | c.292G>T p.A98S | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs1412659623, COSV100418423; called by muse, mutect2, varscan2
- ZNF831 | c.2585C>A p.P862H | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.751); catalogued as COSV100926023, COSV64038770; called by muse, mutect2, varscan2
- ZSCAN32 | c.1039G>A p.G347R (on ENST00000396846; = p.G368R on NM_017810.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.068); catalogued as rs1240520381, COSV100514364; called by muse, mutect2, varscan2
- BMP6 | c.289C>G p.H97D | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.636); called by muse, varscan2
- C14orf93 | c.1168_1170del p.E390del | In Frame Del (DEL) | VAF 64/126 reads (51%) | called by pindel, varscan2
- FSIP2 | c.20066_20069del p.E6689Afs*15 | Frame Shift Del (DEL) | VAF 16/42 reads (38%) | called by mutect2, varscan2
- GSAP | c.1099dup p.C367Lfs*10 | Frame Shift Ins (INS) | VAF 30/81 reads (37%) | called by mutect2, pindel, varscan2
- HOXB3 | c.282del p.A95Hfs*39 | Frame Shift Del (DEL) | VAF 45/104 reads (43%) | called by mutect2, pindel, varscan2
- IGKV2D-29 | c.42G>T p.W14C | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- OR2M3 | c.346del p.A116Lfs*15 | Frame Shift Del (DEL) | VAF 47/376 reads (13%) | called by mutect2, varscan2
- PKNOX2 | c.1188del p.D397Mfs*25 | Frame Shift Del (DEL) | VAF 16/32 reads (50%) | called by mutect2, pindel, varscan2
- TRBV4-1 | c.303G>T p.Q101H | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- ZBTB40 | c.108_109del p.R36Sfs*19 | Frame Shift Del (DEL) | VAF 19/51 reads (37%) | called by mutect2, pindel, varscan2
- ABCA7 | c.5808G>T p.T1936= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs1568427141, COSV54033692; called by muse, mutect2, varscan2
- ABCG1 | c.879A>T p.G293= | Silent (SNP) | VAF 97/177 reads (55%) | catalogued as COSV100494186; called by muse, mutect2, varscan2
- AFF2 | c.3825T>A p.G1275= | Silent (SNP) | VAF 55/109 reads (50%) | catalogued as rs1410176149, COSV99663925; called by muse, mutect2, varscan2
- ALS2 | c.771C>T p.C257= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as rs1007048076, COSV99969279; called by muse, mutect2, varscan2
- AP1B1 | c.24C>A p.T8= | Silent (SNP) | VAF 19/81 reads (23%) | catalogued as COSV100434593; called by muse, mutect2, varscan2
- ARC | c.597C>T p.P199= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV100751708; called by muse, mutect2, varscan2
- ATG9A | c.501T>C p.A167= | Silent (SNP) | VAF 64/122 reads (52%) | catalogued as COSV100036947; called by muse, mutect2, varscan2
- CACNG3 | c.945C>G p.V315= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV99136138; called by mutect2, varscan2
- CCT8L2 | c.615G>T p.V205= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as COSV100742750; called by muse, mutect2, varscan2
- CDH11 | c.1314T>G p.G438= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV99218347; called by muse, mutect2, varscan2
- CDH2 | c.531T>A p.P177= | Silent (SNP) | VAF 50/93 reads (54%) | catalogued as COSV99296875; called by muse, mutect2, varscan2
- CPNE7 | c.1050C>G p.R350= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as COSV99254824; called by muse, mutect2, varscan2
- CRBN | c.804A>G p.L268= | Silent (SNP) | VAF 29/60 reads (48%) | catalogued as rs548391020, COSV99214177; called by muse, mutect2, varscan2
- CSMD1 | c.2229C>T p.D743= (on ENST00000520002; = p.D742= on NM_033225.6) | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as rs751069597, COSV59295070; called by muse, mutect2, varscan2
- CSMD3 | c.2691C>A p.G897= (on ENST00000297405 / NM_001363185.1; = p.G793= on NM_052900.3) | Silent (SNP) | VAF 43/90 reads (48%) | catalogued as rs1275279396, COSV99834050; called by muse, mutect2, varscan2
- CSMD3 | c.1164T>C p.H388= | Silent (SNP) | VAF 56/138 reads (41%) | catalogued as COSV99834054; called by muse, varscan2
- DCK | c.669C>G p.T223= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as COSV99709195; called by muse, mutect2, varscan2
- FAM171B | c.858G>A p.G286= | Silent (SNP) | VAF 17/113 reads (15%) | catalogued as rs147519615; called by muse, mutect2, varscan2
- GALNS | c.624C>T p.I208= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV99243184; called by muse, mutect2, varscan2
- GPR35 | c.390C>T p.P130= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as COSV100166465; called by muse, mutect2, varscan2
- HOXD3 | c.174C>G p.S58= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as COSV99980142; called by muse, mutect2, varscan2
- ICE1 | c.4755G>A p.Q1585= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV99664743; called by muse, mutect2, varscan2
- KANK1 | c.2085C>T p.C695= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as COSV100619746; called by muse, mutect2, varscan2
- KLHL4 | c.654C>A p.A218= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV64145389; called by muse, mutect2, varscan2
- LAMB4 | c.825C>T p.R275= | Silent (SNP) | VAF 37/110 reads (34%) | catalogued as COSV99224024; called by muse, mutect2, varscan2
- LIG1 | c.1645C>A p.R549= | Silent (SNP) | VAF 91/150 reads (61%) | catalogued as COSV99618914; called by muse, mutect2, varscan2
- LMX1A | c.993C>A p.A331= | Silent (SNP) | VAF 48/106 reads (45%) | catalogued as COSV54221294, COSV99672261; called by muse, mutect2, varscan2
- LRP1B | c.9180C>A p.I3060= | Silent (SNP) | VAF 48/150 reads (32%) | catalogued as rs774022861, COSV101256803, COSV67192452; called by muse, mutect2, varscan2
- LRP1B | c.2583G>T p.R861= | Silent (SNP) | VAF 28/92 reads (30%) | catalogued as COSV100796623; called by muse, mutect2, varscan2
- MFAP5 | c.78C>A p.V26= | Silent (SNP) | VAF 29/51 reads (57%) | catalogued as COSV100848140; called by muse, mutect2, varscan2
- MMP16 | c.1104G>T p.V368= | Silent (SNP) | VAF 41/108 reads (38%) | catalogued as COSV99688164; called by muse, mutect2, varscan2
- MUC5AC | c.126C>A p.L42= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as rs1169116491, COSV100650596, COSV62253286, COSV62255365; called by muse, mutect2, varscan2
- NIM1K | c.61C>A p.R21= | Silent (SNP) | VAF 35/107 reads (33%) | catalogued as rs55664335, COSV100390151, COSV58140478; called by muse, mutect2, varscan2
- NPTX2 | c.654C>A p.A218= | Silent (SNP) | VAF 116/330 reads (35%) | catalogued as rs1424964367, COSV99674901; called by muse, mutect2, varscan2
- OR1J1 | c.48C>A p.G16= | Silent (SNP) | VAF 25/98 reads (26%) | catalogued as rs113253939, COSV99403155; called by muse, mutect2, varscan2
- OR5M10 | c.462T>A p.L154= | Silent (SNP) | VAF 29/59 reads (49%) | catalogued as COSV101595884; called by muse, mutect2, varscan2
- OR6T1 | c.66C>A p.L22= | Silent (SNP) | VAF 77/125 reads (62%) | catalogued as rs779847360, COSV58310514; called by muse, mutect2, varscan2
- OR9Q2 | c.312C>T p.F104= | Silent (SNP) | VAF 37/67 reads (55%) | catalogued as rs1206208240, COSV100285440; called by muse, mutect2, varscan2
- PADI4 | c.1416G>A p.V472= | Silent (SNP) | VAF 19/32 reads (59%) | catalogued as COSV100966739; called by muse, mutect2, varscan2
- PDC | c.168T>A p.P56= | Silent (SNP) | VAF 61/97 reads (63%) | catalogued as COSV100414816; called by muse, mutect2, varscan2
- PLS3 | c.630T>C p.H210= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as rs1308669620, COSV56781162; called by muse, mutect2, varscan2
- PRG4 | c.1290C>A p.T430= | Silent (SNP) | VAF 66/105 reads (63%) | catalogued as CD166839, COSV100798204; called by muse, mutect2, varscan2
- PROM2 | c.1764G>T p.L588= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV100468981; called by muse, mutect2, varscan2
- PXDNL | c.2400G>T p.T800= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV100683264, COSV100683600; called by muse, mutect2
- RBM34 | c.1290A>G p.K430= | Silent (SNP) | VAF 85/151 reads (56%) | catalogued as COSV100783958; called by muse, mutect2, varscan2
- RBM6 | c.2703G>T p.L901= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV56483619, COSV99805423; called by muse, mutect2, varscan2
- RNF31 | c.1053G>T p.R351= | Silent (SNP) | VAF 21/39 reads (54%) | catalogued as COSV99396048; called by muse, mutect2, varscan2
- RPTN | c.447T>A p.P149= | Silent (SNP) | VAF 293/526 reads (56%) | catalogued as COSV100285492; called by muse, mutect2, varscan2
- SALL3 | c.2352C>A p.A784= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV101609998; called by muse, mutect2, varscan2
- SEPTIN9 | c.1098C>T p.F366= (on ENST00000427177 / NM_001113491.2; = p.F348= on NM_006640.4) | Silent (SNP) | VAF 21/44 reads (48%) | catalogued as rs199574222, COSV61207366; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLAMF8 | c.711G>A p.V237= | Silent (SNP) | VAF 30/190 reads (16%) | catalogued as COSV99222919; called by muse, mutect2, varscan2
- SYNJ1 | c.993A>G p.L331= | Silent (SNP) | VAF 27/48 reads (56%) | catalogued as COSV100449302; called by muse, mutect2, varscan2
- TIMP4 | c.243C>T p.F81= | Silent (SNP) | VAF 27/48 reads (56%) | catalogued as COSV99826018; called by muse, mutect2, varscan2
- TMC2 | c.1569C>A p.A523= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs771788005, COSV100727603; called by muse, mutect2
- TNRC18 | c.8823C>T p.S2941= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs575914521, COSV51875709; called by muse, mutect2
- TRBV5-1 | c.315G>T p.S105= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as rs369042285; called by muse, mutect2, varscan2
- TRIM21 | c.720A>C p.A240= | Silent (SNP) | VAF 32/50 reads (64%) | catalogued as rs1012280508, COSV99587695; called by muse, mutect2, varscan2
- TRIM50 | c.645C>A p.A215= | Silent (SNP) | VAF 24/97 reads (25%) | catalogued as COSV60796855; called by muse, mutect2, varscan2
- TRPC4 | c.324C>G p.V108= | Silent (SNP) | VAF 28/68 reads (41%) | catalogued as COSV100156830, COSV59011862; called by muse, mutect2, varscan2
- UBN1 | c.2379C>A p.P793= | Silent (SNP) | VAF 26/77 reads (34%) | catalogued as COSV99278034; called by muse, mutect2, varscan2
- UNC5C | c.2082G>C p.S694= | Silent (SNP) | VAF 13/19 reads (68%) | catalogued as COSV101497788, COSV71659026; called by muse, mutect2, varscan2
- USH1C | c.318G>T p.L106= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as rs1442968310, COSV99140004; called by muse, mutect2, varscan2
- USP34 | c.5406A>G p.P1802= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as rs1215390304, COSV101277024; called by muse, mutect2, varscan2
- VANGL2 | c.1083G>T p.V361= | Silent (SNP) | VAF 11/101 reads (11%) | catalogued as COSV100925571; called by muse, mutect2, varscan2
- VIPR2 | c.219G>T p.V73= | Silent (SNP) | VAF 26/56 reads (46%) | catalogued as COSV100057166; called by muse, mutect2, varscan2
- WDR59 | c.1635C>T p.C545= | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as rs754246026, COSV50937582; called by muse, mutect2, varscan2
- WDR7 | c.1653A>G p.K551= | Silent (SNP) | VAF 41/72 reads (57%) | catalogued as COSV54348630, COSV99589457; called by muse, mutect2, varscan2
- WSCD1 | c.816C>A p.T272= | Silent (SNP) | VAF 18/37 reads (49%) | catalogued as rs753995970, COSV100496566, COSV100496886; called by muse, mutect2, varscan2
- ZAN | c.7455C>A p.A2485= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as rs1178744405, COSV100769703; called by muse, mutect2, varscan2
- ZNF667 | c.138T>C p.N46= | Silent (SNP) | VAF 65/92 reads (71%) | catalogued as COSV52637784, COSV99410435; called by muse, mutect2, varscan2
- ZNF711 | c.2196A>C p.P732= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as COSV99341045; called by muse, mutect2, varscan2
- AL049634.2 | c.431-5592C>A | Intron (SNP) | VAF 37/90 reads (41%) | catalogued as rs1400386115, COSV101064911; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65498970 C>A | 5'Flank (SNP) | VAF 28/53 reads (53%) | called by muse, mutect2, varscan2
- COLCA2 | chr11:111296285 T>G | 5'Flank (SNP) | VAF 35/58 reads (60%) | called by muse, mutect2, varscan2
- DPF3 | c.871+2944C>A | Intron (SNP) | VAF 19/37 reads (51%) | catalogued as COSV100818561; called by muse, mutect2, varscan2
- NXF5 | n.477C>T | RNA (SNP) | VAF 53/134 reads (40%) | catalogued as COSV99534384; called by muse, mutect2, varscan2
